Gene-level copy-number profile of tumor specimen C3N-01200-05 from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca5b2ae6-b6a1-4456-b411-c1d0988656dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01200-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/3bb8d742-d106-49df-9ea8-5efadde5a25a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,238; copy number 1: 5,954; copy number 2: 50,662; copy number 3: 550; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 1,238 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:57,200,507–57,268,905, 1 gene: EXOC5.
- chr14:60,396,469–106,879,812, 1,237 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:133,778,246–133,778,699, 2 genes, copy number 15: RPL23AP60, BX322534.1.

Autosomal genes at a single copy (total copy number 1): 5,954. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
